Gene-level copy-number profile of tumor specimen TCGA-L5-A8NR-01A from TCGA case TCGA-L5-A8NR, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage III; Tumor grade: GX; Age at diagnosis: 81.4 years (29,730 days).
Specimen TCGA-L5-A8NR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.8631793d-9ee4-4bb4-b6ea-36d4b84a7b0d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-L5-A8NR-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 817 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/2b3039eb-849a-4057-b40d-05b53bcc25e8

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 12; copy number 1: 1,961; copy number 2: 14,540; copy number 3: 35,003; copy number 4: 4,905; copy number 5: 2,638; copy number 6: 235; copy number 7: 149; copy number 8: 64; copy number 9: 95; copy number 10: 38; copy number 11: 28; copy number 12: 5; copy number 15: 20; copy number 16: 9; copy number 19: 6; copy number 26: 46; copy number 27: 27; copy number 28: 11; copy number 31: 14.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-L5-A8NR-01A-11D-A37B-01): tumor purity 0.67, ploidy 2.87, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 12 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:60,616,822–60,856,605, 6 genes: AC104164.2, MIR548BB, PPIAP70, AC104164.1, PPIAP71, U3.
- chr16:78,495,926–78,826,006, 6 genes (within-gene range 0–2): AC046158.1, AC046158.4, AC046158.2, AC046158.3, AC009141.1, RPS3P7.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 428 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:73,026,748–76,421,868, 83 genes, copy number 7–26 (broad region; genes not listed).
- chr4:76,509,284–76,575,626, 4 genes, copy number 11: AC112249.1, RNU6-145P, MIR4450, MIR548AH.
- chr4:142,023,160–144,343,750, 28 genes, copy number 9–12 (within-gene range 4–12): INPP4B, RPL5P13, LSM3P4, AC139720.2, AC139720.1, AC104596.1, AC104596.2, USP38, AC097658.2, Y_RNA, GAB1, MIR3139, AC097658.1, AC097658.3, RPSAP36, AC104685.1, SMARCA5-AS1, SMARCA5, AC139713.1, AC107223.1, GUSBP5, FREM3, AC104090.1, GYPE, AC093890.1, GYPB, AC093890.2, GYPA.
- chr4:152,320,544–152,536,092, 1 gene, copy number 16 (within-gene range 2–16): FBXW7.
- chr4:152,448,275–154,491,799, 35 genes, copy number 10–16 (within-gene range 2–16): AC023424.2, MIR3140, MIR4453HG, MIR4453, RPS3AP18, AC023424.1, TMEM154, AC106882.1, TIGD4, ARFIP1, NSA2P6, FAM192BP, AC093599.2, FHDC1, AC093599.1, TRIM2, AC013477.1, RNU6-1196P, Y_RNA, ANXA2P1, MND1, RN7SL419P, TMEM131L, AC106865.2, AC106865.1, WDR45P1, TLR2, RNF175, AC020703.1, SFRP2, AC079298.3, DCHS2, AC079298.1, AC079298.2, AC110775.1.
- chr6:53,497,341–55,579,197, 27 genes, copy number 8: GCLC, AL033397.2, AL033397.1, LINC01564, KLHL31, AL590652.1, LRRC1, AL033384.2, MLIP, AL033384.1, MLIP-AS1, MLIP-IT1, ERHP2, AL359380.1, TINAG, TINAG-AS1, CLNS1AP1, RPL10P10, RPSAP44, KRASP1, RNU6-1023P, AL512363.1, FAM83B, AL049555.1, HCRTR2, GFRAL, HMGCLL1.
- chr17:39,238,466–40,017,813, 30 genes, copy number 7–27 (within-gene range 2–27): AC015910.1, FBXL20, AC005288.1, MED1, CDK12, RNU6-233P, AC009283.1, NEUROD2, AC087491.1, PPP1R1B, STARD3, TCAP, PNMT, PGAP3, ERBB2, MIR4728, MIEN1, GRB7, IKZF3, KRT8P34, AC090844.1, ZPBP2, GSDMB, ORMDL3, AC090844.2, LRRC3C, GSDMA, PSMD3, AC090844.3, CSF3.
- chr17:40,026,332–40,027,645, 2 genes, copy number 27: MIR6884, SNORD124.
- chr19:29,001,670–35,869,287, 218 genes, copy number 7–11 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,632. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
